Somatic mutation profile of tumor specimen TCGA-2Y-A9GT-01A (aliquot TCGA-2Y-A9GT-01A-11D-A382-10) from TCGA case TCGA-2Y-A9GT, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.4 years (18,768 days).
Specimen TCGA-2Y-A9GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b36c45c5-aed3-4294-88c1-1111d4da721d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GT-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GT-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dd32d1d-5d07-4491-af3d-451d8504c594

The open-access MAF lists 93 somatic variants for this specimen: 73 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 17, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Intron 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG1 | c.42C>A p.C14* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV101268822; called by muse, mutect2, varscan2
- ABHD12 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546873766, COSV100194318; called by muse, mutect2, varscan2
- AGBL1 | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); catalogued as COSV101407962; called by muse, mutect2, varscan2
- AKAP11 | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs763351585, COSV99213730; called by muse, mutect2, varscan2
- ALG10B | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100439864; called by muse, mutect2, varscan2
- ATR | c.2743G>A p.V915I | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100637962; called by muse, mutect2, varscan2
- BOC | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs770329941, COSV56348197; called by muse, mutect2, varscan2
- CBLL2 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 105/189 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.399); catalogued as COSV100081434, COSV100081535; called by muse, mutect2, varscan2
- CELSR1 | c.7141A>G p.S2381G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV99417647; called by muse, mutect2, varscan2
- CIT | c.1890C>G p.I630M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs1414046793, COSV99949099; called by muse, mutect2, varscan2
- CLCN5 | c.221T>A p.L74* | Nonsense Mutation (SNP) | VAF 48/96 reads (50%) | catalogued as COSV100259983; called by muse, mutect2, varscan2
- COL15A1 | c.860T>G p.F287C | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100897562; called by muse, mutect2, varscan2
- CSMD1 | c.2778C>A p.S926R (on ENST00000520002; = p.S925R on NM_033225.6) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100146185, COSV104408933; called by muse, mutect2, varscan2
- DAPP1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV99596769; called by muse, mutect2, varscan2
- DIPK2B | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933417; called by muse, mutect2, varscan2
- DNAAF2 | c.2390A>G p.N797S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100023470; called by muse, mutect2, varscan2
- DOCK2 | c.4665T>A p.Y1555* | Nonsense Mutation (SNP) | VAF 39/163 reads (24%) | catalogued as COSV99911374; called by muse, mutect2, varscan2
- DOCK3 | c.2167A>G p.I723V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs763769250, COSV56542083, COSV99810680; called by muse, mutect2, varscan2
- DPYD | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100928889; called by muse, mutect2, varscan2
- EDC4 | c.3433A>G p.T1145A | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100197575; called by muse, mutect2, varscan2
- EEF1A1 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58549126, COSV58550350; called by muse, mutect2, varscan2
- EHMT1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs1369733741, COSV100603639; called by muse, mutect2, varscan2
- EPM2AIP1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); catalogued as COSV99212387; called by muse, mutect2, varscan2
- ESRRG | c.1133-2A>T p.X378_splice | Splice Site (SNP) | VAF 44/160 reads (28%) | catalogued as COSV100752625; called by muse, mutect2, varscan2
- ESRRG | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.922); catalogued as COSV100752627; called by muse, mutect2, varscan2
- G6PC | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99520721; called by muse, mutect2, varscan2
- GLI2 | c.2342T>C p.M781T (on ENST00000361492 / NM_001374353.1; = p.M798T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV100082821; called by muse, mutect2, varscan2
- GLIPR1L2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs550463995, COSV57553070, COSV57553633; called by muse, mutect2, varscan2
- HMG20A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100287716; called by muse, mutect2, varscan2
- KCNA5 | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV52904032, COSV99363787; called by muse, mutect2, varscan2
- KCTD16 | c.1277A>T p.Y426F | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101568776; called by muse, mutect2, varscan2
- KLRC3 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV101122901; called by mutect2, varscan2
- KRTAP6-1 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | PolyPhen benign (0.007); catalogued as COSV100228750; called by muse, mutect2, varscan2
- LILRB5 | c.1541C>A p.A514D (on ENST00000449561 / NM_001081442.3; = p.A513D on NM_006840.5) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100300227; called by muse, mutect2, varscan2
- MAPKAP1 | c.1349A>G p.H450R (on ENST00000265960 / NM_001006617.3; = p.H414R on NM_024117.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.09); catalogued as rs1460570415, COSV99784645; called by muse, mutect2, varscan2
- MAST4 | c.6625G>T p.D2209Y (on ENST00000403625 / NM_001164664.2; = p.D2020Y on NM_015183.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55120102, COSV99843640; called by muse, mutect2, varscan2
- MBD5 | c.2088T>G p.F696L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV101290018; called by muse, mutect2, varscan2
- MED15 | c.1244T>A p.I415N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.192); catalogued as COSV99487558; called by muse, mutect2, varscan2
- MIIP | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV99337505; called by muse, mutect2, varscan2
- MMRN1 | c.2974G>T p.G992C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV99306848; called by muse, mutect2, varscan2
- MTSS1 | c.2177del p.P726Hfs*7 | Frame Shift Del (DEL) | VAF 21/108 reads (19%) | catalogued as COSV99412803; called by mutect2, pindel, varscan2
- NCK2 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99255540; called by muse, mutect2, varscan2
- NEBL | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs369862013, COSV101008908; called by muse, mutect2, varscan2
- NKX2-8 | c.466T>G p.S156A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99352301; called by muse, mutect2, varscan2
- NPAS3 | c.634A>C p.M212L (on ENST00000356141 / NM_001164749.2; = p.M180L on NM_022123.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as rs905978928, COSV100387243; called by muse, mutect2, varscan2
- OR4A15 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100123960; called by muse, mutect2, varscan2
- OR5B17 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV100641875; called by muse, mutect2, varscan2
- PLPP6 | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99794863; called by muse, mutect2, varscan2
- PPP6R2 | c.1577C>A p.T526K | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99324070; called by muse, mutect2, varscan2
- PTPRN | c.425T>C p.L142S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1214987031, COSV99833860; called by muse, mutect2, varscan2
- SEMA6C | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as COSV100501218; called by muse, mutect2, varscan2
- SERPIND1 | c.1221G>T p.E407D | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99300119; called by muse, mutect2, varscan2
- SHANK3 | c.2258G>T p.R753L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53184016; called by muse, mutect2
- SHOC1 | c.2112A>T p.R704S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100597452; called by muse, mutect2, varscan2
- SIPA1L2 | c.3869T>C p.I1290T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV99477750; called by muse, mutect2, varscan2
- SLC8A2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763617613, COSV52642875, COSV99369795; called by muse, mutect2, varscan2
- SOGA3 | c.1457T>C p.L486S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100846858; called by muse, mutect2, varscan2
- SUSD1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100813251, COSV62582729; called by muse, mutect2, varscan2
- SYNGR3 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV50192352, COSV99937231; called by muse, mutect2, varscan2
- TMEM201 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777509881, COSV61052201; called by muse, mutect2, varscan2
- TPR | c.5990G>A p.G1997D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV100823789; called by muse, mutect2, varscan2
- TRERF1 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as rs777652690, COSV100550418; called by muse, mutect2, varscan2
- UGT2B15 | c.1197T>A p.D399E | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as COSV100592268; called by muse, mutect2
- VWA3B | c.1114+1G>A p.X372_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV101345991; called by muse, mutect2, varscan2
- ZBED2 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as rs1404452656, COSV51924706, COSV99342641; called by muse, mutect2, varscan2
- ZC3H12A | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100897682; called by muse, mutect2, varscan2
- ZNF280B | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100840234, COSV64529700; called by muse, mutect2, varscan2
- ZNF556 | c.859T>A p.Y287N | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100298677; called by muse, mutect2, varscan2
- ZNF669 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.917); catalogued as COSV100594242; called by muse, mutect2, varscan2
- ZSCAN21 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV99460857; called by muse, mutect2, varscan2
- INO80 | c.3618del p.M1207Wfs*7 | Frame Shift Del (DEL) | VAF 35/151 reads (23%) | called by mutect2, pindel, varscan2
- IPO8 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- L3MBTL1 | c.1990_1997del p.C664Rfs*6 (on ENST00000418998 / NM_001377303.1; = p.C574Rfs*6 on NM_015478.7) | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- ARMCX6 | c.21G>T p.V7= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV100726226; called by muse, mutect2, varscan2
- BRSK1 | c.1131C>T p.P377= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as COSV100473856; called by mutect2, varscan2
- CLCA1 | c.1317C>T p.P439= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99322142; called by muse, mutect2, varscan2
- CPNE8 | c.1044A>G p.G348= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV100504189; called by muse, mutect2, varscan2
- DIP2C | c.507C>T p.H169= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs145952021; called by muse, mutect2, varscan2
- GPR152 | c.99G>T p.T33= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV100351479; called by muse, mutect2, varscan2
- MROH7 | c.81G>A p.P27= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs371606173; called by muse, mutect2, varscan2
- NBEAL2 | c.6412A>C p.R2138= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV99435462; called by muse, mutect2, varscan2
- NECAP2 | c.63C>T p.I21= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100130774; called by muse, mutect2, varscan2
- PLCB2 | c.1645C>T p.L549= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs766373645, COSV99541822; called by muse, mutect2, varscan2
- RAB40AL | c.747C>T p.H249= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV99505053; called by muse, mutect2, varscan2
- SLC6A14 | c.846A>G p.R282= | Silent (SNP) | VAF 96/238 reads (40%) | catalogued as COSV100903107; called by muse, mutect2, varscan2
- TAF1 | c.4485C>T p.V1495= (on ENST00000373790 / NM_138923.4; = p.V1516= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV99335266; called by muse, mutect2, varscan2
- TM6SF1 | c.178C>A p.R60= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV99362558; called by muse, mutect2
- TP53BP1 | c.1380T>A p.I460= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99780213; called by muse, mutect2, varscan2
- TSPAN4 | c.18C>T p.L6= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100672744; called by muse, mutect2, varscan2
- WNT11 | c.117G>A p.L39= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100490293; called by muse, mutect2, varscan2
- AP003393.1 | n.514+801dup | Intron (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-86043A>T | Intron (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- S1PR3 | chr9:88991164 A>G | 5'Flank (SNP) | VAF 33/139 reads (24%) | catalogued as COSV100560836; called by muse, mutect2, varscan2
